Gene-level copy-number profile of tumor specimen TARGET-40-0A4HXS-01A from TARGET case TARGET-40-0A4HXS, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 23.2 years (8,470 days).
Specimen TARGET-40-0A4HXS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.10ba0d9f-d287-5c8d-a6b3-69e4fb599de2.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-0A4HXS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 406 have no estimate.
https://portal.gdc.cancer.gov/files/cdd52d58-8072-4e18-a02b-2db10c09f73a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 2,898; copy number 2: 7,495; copy number 3: 10,749; copy number 4: 30,495; copy number 5: 3,246; copy number 6: 2,772; copy number 7: 1,293; copy number 8: 16; copy number 9: 149; copy number 10: 64; copy number 11: 73; copy number 12: 81; copy number 13: 83; copy number 15: 66; copy number 17: 98; copy number 18: 147; copy number 19: 13; copy number 20: 61; copy number 21: 5; copy number 22: 45; copy number 24: 75; copy number 25: 54; copy number 26: 3; copy number 27: 100; copy number 29: 38; copy number 30: 48; copy number 31: 27; copy number 36: 21.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:9,480,608–9,576,275, 2 genes: AC092821.1, AC092821.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,251 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,795,527–37,034,515, 1 gene, copy number 11 (within-gene range 6–11): GRIK3.
- chr1:149,782,671–151,459,494, 98 genes, copy number 17 (within-gene range 7–17) (broad region; genes not listed).
- chr1:152,399,577–152,566,780, 5 genes, copy number 13: HMGN3P1, CRNN, LCE5A, CRCT1, LCE3E.
- chr1:152,622,834–154,220,637, 109 genes, copy number 9–13 (broad region; genes not listed).
- chr2:88,811,186–88,861,563, 1 gene, copy number 15 (within-gene range 5–15): AC244205.1.
- chr2:88,857,161–89,117,844, 24 genes, copy number 15: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17.
- chr4:68,509,441–68,670,652, 6 genes, copy number 11: UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr8:47,089,572–49,229,174, 41 genes, copy number 13–20 (within-gene range 2–20): AC120036.1, RPL10AP2, NDUFA5P12, AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1, SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3, RNU6-665P, CEBPD, PRKDC, Y_RNA, AC021236.1, MCM4, RNU6-519P, UBE2V2, AC104989.1, IDI1P2, RNU6-295P, RNA5SP531, RPL29P19, AC041040.1, AC026904.2, AC022915.2, LINC02599, LINC02847, AC022915.1, AC022915.3, EFCAB1, AC100805.1, AC013701.1, SNAI2, AC013701.2, AC044893.2, PPDPFL, AC044893.1.
- chr8:106,359,476–114,791,929, 68 genes, copy number 9–11 (within-gene range 2–11) (broad region; genes not listed).
- chr8:116,642,130–133,134,903, 234 genes, copy number 9–15 (within-gene range 6–15) (broad region; genes not listed).
- chr15:94,841,059–95,169,864, 1 gene, copy number 25 (within-gene range 4–25): AC087633.2.
- chr15:95,034,108–99,105,824, 72 genes, copy number 22–25 (broad region; genes not listed).
- chr17:14,177,131–22,706,703, 406 genes, copy number 15–31 (broad region; genes not listed).
- chr21:14,757,588–15,014,430, 6 genes, copy number 12 (within-gene range 1–12): POLR2CP1, GAPDHP16, AF127577.4, LINC02246, RBMX2P1, AF127577.3.
- chr21:14,961,309–14,964,233, 1 gene, copy number 12: AF127577.1.
- chr21:21,933,315–24,114,352, 27 genes, copy number 11–13 (within-gene range 1–13): AP000472.1, LINC01687, LINC00308, AP000705.2, AP000705.1, RNU4-45P, AP000561.1, MAPK6P2, AP000959.1, AP000949.1, AP001116.1, MIR6130, ZNF299P, MSANTD2P1, AP001255.1, RNU2-55P, D21S2088E, EEF1A1P1, TUBAP1, Y_RNA, AP000459.1, AP000961.1, AP000474.2, AP000474.1, AP000477.2, AP000477.3, AP000477.1.
- chr21:27,722,379–33,588,706, 151 genes, copy number 19–36 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 534. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
